CGCI case BLGSP-71-06-00005 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/84177457-b898-4eb3-bda8-f6b8d2d1e4be

Demographics
Sex at birth: male; Race: black or african american; Age at index: 5 years; Vital status: Dead; Days to death: 315 days.

Diagnoses (2)
1. Burkitt lymphoma, NOS (Includes all variants) (the primary disease): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bones of skull and face and associated joints; Classification of tumor: primary; Age at diagnosis: 5.2 years (1,892 days); Year of diagnosis: 2013; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage II; Ann Arbor B symptoms: Yes; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 315 days; Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Immunodeficiency-associated, pediatric; Max tumor bulk site: Maxilla; Sites of involvement: Eye / Maxilla.
   Pathology details: Lymph node involved site: Submandibular.
   Pathology details: Bone marrow malignant cells: No; Lymph node involved site: Cervical, NOS; Tumor largest dimension diameter: 8 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: COM; Days to treatment start: 5 days; Days to treatment end: 89 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Methotrexate + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 5 days; Days to treatment end: 89 days; Number of cycles: 6; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Treatment intent type: Adjuvant; Regimen or line of therapy: DHAP; Days to treatment start: 255 days; Days to treatment end: 287 days; Number of cycles: 2; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Cytarabine + Dexamethasone; Treatment intent type: Adjuvant; Days to treatment start: 255 days; Days to treatment end: 287 days; Number of cycles: 2; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; Radiation Therapy, NOS, for recurrent disease; Surgery, NOS, for recurrent disease.
2. Tumor, NOS: Tissue or organ of origin: Testis, NOS; Classification of tumor: Synchronous primary; Age at diagnosis: 5.8 years (2,135 days); Days to diagnosis: 243 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (3 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 80; ECOG performance status: 1.
- Days to follow up: 243 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 243 days; Evidence of recurrence type: Biopsy with Histologic Confirmation.
- Follow-up contact recording only the day: day 315.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- MYC translocation (FISH): Positive.
- Lactate Dehydrogenase 437 [Blood test normal range upper: 340].

Other clinical attributes
- Day 0: Comorbidities: HIV/AIDS.
- Day 0: Risk factors: HIV/AIDS.
- Day 0: Weight: 16 kg; CD4 count: 871; Haart treatment indicator: No; HIV viral load: 2625.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-06-00005-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Maxilla; Preservation method: Frozen; Days to sample procurement: 0 days; Initial weight: 240 mg; Method of sample procurement: Incisional Biopsy; Tissue collection type: Prospective.
  Slide BLGSP-71-06-00005-01A-01-S2-HE: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 45; Percent monocyte infiltration: 30; Percent neutrophil infiltration: 5.
  Slide BLGSP-71-06-00005-01A-02-S1-HE: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 90; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 10; Percent lymphocyte infiltration: 50; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 10.
- Sample BLGSP-71-06-00005-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample BLGSP-71-06-00005-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-06-00005-01-CD3-1: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-BCL2-1-20X: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-CD20: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-Ki67-1: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-HE-1: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-BCL6: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-Ki67-1-20X: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-BCL2-1: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-CD10-1-20X: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-HE: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-BCL6-1-20X: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-CD3-1-20X: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-CD20-1-20X: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-CD20-1: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-BCL2: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-HE-1-20X: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-CD10: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-CD10-1: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-Ki67: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-CD3: Tissue microarray coordinates: D2,A3,F5.
  Slide BLGSP-71-06-00005-01-BCL6-1: Tissue microarray coordinates: D2,A3,F5.
- Sample BLGSP-71-06-00005-99A: Sample type: Granulocytes; Tissue type: Normal; Specimen type: Granulocytes; Preservation method: Frozen; Days to sample procurement: 0 days; Method of sample procurement: Blood Draw; Tissue collection type: Prospective.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: With tumor; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Haart therapy prior to diagnosis: No; Haart therapy at diagnosis: No.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 2; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: cervical.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Eye.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 437; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Follow-up form: New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event 1: New tumor event type: Locoregional Recurrence; New tumor event site: Lymph Node(s); New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form, New tumor event 2: New tumor event type: New Primary Tumor; New tumor event site other: testes; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment 1: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 6.
- Treatments, Treatment 2: Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharma adjuvant cycles count: 2; Treatment best response: Clinical Progressive Disease.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_FFPESets_20210126.xlsx, for sample BLGSP-71-06-00005-01B-01E-8718-01:
- % tumour top: 90
- Tumour Quality: Good

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_FFPESets_20210126.xlsx, for sample BLGSP-71-06-00005-01B-01S-8718-01:
- % tumour top: 90
- Tumour Quality: Good

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-06-00005-01B-01E-0001-01:
- % tumour: 90
